Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A3ST, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A3ST-01A (Primary Tumor).

[page 1 of 3]
LABORATORY MEDICINE PROGRAM

Surgical Pathology Consultation Report

ICD-O-3
carcinoma, papillary,
follicular variant

Specimen(s) Received

1. Thyroid: total thyroid stich marks upper pole left lobe

Site: thyroid, NOS

8340/3

C73.9 4/3/20

Diagnosis

Multifocal papillary carcinoma, dominant angioinvasive and widely invasive follicular variant with focal dedifferentiation (less than 10% of tumor) 5.4 cm, right; follicular nodular disease: Thyroid

No pathological diagnosis: Lymph node, 1, right perithyroidal

-Total thyroidectomy specimen. See Comment.

Comment

The dominant tumor is predominantly a follicular variant papillary carcinoma. Within this tumor, there are regions which focally show a more solid architecture associated with increased single cell apoptosis, away from areas of degeneration, consistent with dedifferentiation. These areas represent only a small portion of the tumor (less than 10%).

This case has been seen in consultation with Dr. [redacted] and she agrees with the interpretation and diagnosis.

Synoptic Data

Procedure:	Total thyroidectomy
Received:	Fresh
Specimen Integrity:	Intact
Specimen Size:	Right lobe:
	6.8 cm
	5.7 cm
	4.0 cm
	Left lobe:
	4.0 cm
	1.5 cm
	1.3 cm
	Isthmus +/- pyramidal lobe:
	2.5 cm
	0.5 cm
	0.4 cm
Specimen Weight:	56.5 g
Tumor Focality:	Multifocal, bilateral
	Multifocal, midline (isthmus)

[page 2 of 3]
Surgical Pathology Consultation Report

----- DOMINANT TUMOR -----

Tumor Laterality: Right lobe
Tumor Size: Greatest dimension: 5.4cm
Additional dimension: 3.7 cm
Additional dimension: 3.0 cm
Histologic Type: Papillary carcinoma, follicular variant
Follicular architecture
Other architecture: focal dedifferentiation (less than 10% of tumor).
Classical cytomorphology
Histologic Grade: Not applicable
Margins: Margins uninvolved by carcinoma
Tumor Capsule: Partially encapsulated
Tumor Capsular Invasion: Present, extent widely invasive
Lymph-Vascular Invasion: Present, focal extent (less than 4 vessels)
Perineural Invasion: Not identified
Extrathyroidal Extension: Not identified

----- SECOND TUMOR -----

Tumor Laterality: Left lobe
Tumor Size: Greatest dimension: 1.0cm
Histologic Type: Papillary carcinoma, follicular variant
Follicular architecture
Oncocytic or oxyphilic cytomorphology
Histologic Grade: Not applicable
Margins: Margins uninvolved by carcinoma
Distance of invasive carcinoma to closest margin: 0.1mm
Tumor Capsule: Partially encapsulated
Tumor Capsular Invasion: Not identified
Lymph-Vascular Invasion: Not identified
Perineural Invasion: Not identified
Extrathyroidal Extension: Not identified
TNM Descriptors: m (multiple primary tumors)
Primary Tumor (pT): pT3: Tumor more than 4 cm, limited to thyroid or with minimal extrathyroidal extension
(eg, extension to sternothyroid muscle or perithyroid soft tissues)
Regional Lymph Nodes (pN): pN0: No regional lymph node metastasis
Number of regional lymph nodes examined: 1
Number of regional lymph nodes involved: 0
Distant Metastasis (pM): Not applicable
Additional Pathologic Findings: Adenomatoid nodule(s) or Nodular follicular disease
Other: Multiple additional papillary microcarcinomas identified (all 0.6 cm or less in size) in right lobe, isthmus, and left lobe.

*Pathologic Staging is based on AJCC/UICC TNM, Edition

Electronically verified by:

Clinical History

thyroid mass

Gross Description

The specimen labeled with the patient's name and as "Total thyroid, stitch marks upper pole left lobe" consists of a thyroid gland that is received oriented with a suture and weighs 56.5 g. The right lobe measures 6.8 cm SI x 5.7 cm ML x 4.0 cm AP, the left lobe measures 4.0 cm SI x 1.5 cm ML x 1.3 cm AP and the isthmus measures 2.5 cm SI x 0.5 cm ML x 0.4 cm AP. The external surfaces have fibrous adhesions, and are painted with silver nitrate. No parathyroid glands and/or lymph nodes are identified grossly. The right lobe contains a pink-tan and fleshy, well delineated, non-encapsulated

[page 3 of 3]
Surgical Pathology Consultation Report

nodule that measures 5.4 cm SI x 3.7 cm ML x 3.0 cm . . . The left lobe contains at least 3 well circumscribed, fleshy nodules that range from 0.5 to 1.0 cm in diameter. The remainder of the thyroid tissue is grossly unremarkable. Sections of all the nodules and normal tissue are stored frozen. Representative sections of the remainder of the specimen are submitted as follows:

1A-O representative of right lobe, superior to inferior

1P isthmus, in toto

1Q-T left lobe superior to inferior, in toto

Source: NCI Genomic Data Commons file a1081003-b6db-4d85-bf9e-086562d01faf (TCGA-EM-A3ST.1056960E-3020-440D-976D-B29BFCC93991.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).